Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TU, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TU-01A (Primary Tumor).

ICD-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9

Breast, right, simple mastectomy: Infiltrating ductal carcinoma, Nottingham grade III (of III), forming a well circumscribed mass (4.2 x 4.0 x 3.0 cm) (AJCC pT2) in the lower outer quadrant. Extensive tumor necrosis is present. There is no associated in situ component. The nipple is uninvolved. The surgical resection margins are negative for tumor. The closest margin (deep) is free by 0.3 cm. The surrounding breast tissue shows non-proliferative fibrocystic changes.

Lymph nodes, right axillary sentinel Nos. 1A, 1B, 1C, and 2, excision: Multiple (4) right axillary sentinel lymph nodes are negative for tumor. Blue dye is identified in lymph nodes Nos. 1A and 1B. No blue dye is present in lymph nodes 1C or 2 [AJCC pN0(sn)]. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

HER2/neu protein overexpression is negative, score of 1+, according to the interpretation guidelines in the FDA-approved HercepTest.

Estrogen: Negative, 0% nuclear staining

Progesterone: Negative, 0% nuclear staining

ER (Estrogen Receptor) test was developed and its performance characteristics determined by . It has not been cleared or approved by the U.S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 413d80f7-42ba-4485-90cf-b032f4bb0c80 (TCGA-AR-A0TU.81A39E94-059E-4307-A75A-E8C051E9D0C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).